MMRF case MMRF_1290 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/4159c7b8-c8a4-435d-ac98-9205b6ac353d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 55 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 56.0 years (20,439 days); ISS stage: III; Days to last known disease status: 1,537 days (4.2 years); Days to last follow up: 1,537 days (4.2 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 86 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days; Days to treatment end: 86 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 7 days; Days to treatment end: 86 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 130 days; Days to treatment end: 130 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 131 days; Days to treatment end: 131 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 206 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 0): M Protein 8.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.12 mg/dL; Immunoglobulin G 102 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 8.17 µg/mL; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.84 ×10⁹/L; Platelets 88 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.28 mmol/L; Albumin 26 g/L; Total Protein 12 g/dL; Glucose 5.61 mmol/L; C-Reactive Protein 0.086 mg/dL.
- Day 89 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 6.45 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 1.51 µg/mL; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.43 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 5.8 g/dL; Glucose 6.05 mmol/L.
- Day 158 (ECOG 1): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 4.56 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.39 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 5.39 mmol/L.
- Day 207 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.65 mg/dL; Immunoglobulin G 5.61 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 1.33 µg/mL; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.46 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 5.56 mmol/L.
- Day 368 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.97 mg/dL; Immunoglobulin G 7.93 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 1.21 µg/mL; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.53 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 4.95 mmol/L.
- Day 438 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.86 mg/dL; Immunoglobulin G 7.83 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 1.49 µg/mL; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.35 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 5.67 mmol/L.
- Day 550 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.78 mg/dL; Immunoglobulin G 8.94 g/L; Immunoglobulin A 0.72 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 1.55 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.62 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 5.45 mmol/L.
- Day 634 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.94 mg/dL; Immunoglobulin G 9.52 g/L; Immunoglobulin A 1.09 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 1.49 µg/mL; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.87 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 6.9 g/dL; Glucose 5.56 mmol/L.
- Day 717 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 8.51 g/L; Immunoglobulin A 1.4 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 1.69 µg/mL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 5.73 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 7.5 g/dL; Glucose 6.93 mmol/L.
- Day 816: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.72 mg/dL; Immunoglobulin G 9.85 g/L; Immunoglobulin A 2.07 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 2.72 µg/mL; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.36 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 32 g/L; Total Protein 7 g/dL; Glucose 5.78 mmol/L.
- Day 865 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Immunoglobulin G 9.39 g/L; Immunoglobulin A 1.39 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 1.57 µg/mL; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.29 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 5.34 mmol/L.
- Day 949 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.87 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 1.47 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 1.59 µg/mL; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.37 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 7.4 g/dL; Glucose 6.22 mmol/L.
- Day 1,033: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.15 mg/dL; Immunoglobulin G 9.92 g/L; Immunoglobulin A 1.92 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 1.59 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 0.98 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 4.95 mmol/L.
- Day 1,117: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.94 mg/dL; Immunoglobulin G 9.69 g/L; Immunoglobulin A 1.97 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 1.47 µg/mL; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.25 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.7 g/dL; Glucose 5.5 mmol/L.
- Day 1,229: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.83 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 2.22 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 1.63 µg/mL; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.59 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 6.9 g/dL; Glucose 6.99 mmol/L.
- Day 1,369 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.61 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 2.25 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 1.31 µg/mL; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 5.17 mmol/L.
- Day 1,453 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.68 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 2.29 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 1.26 µg/mL; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.68 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 5.45 mmol/L.
- Day 1,537: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.2 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 2.28 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 1.35 µg/mL; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.44 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 7.1 g/dL; Glucose 5.45 mmol/L.

Other clinical attributes
- Day -3: Weight: 74 kg; Height: 170 cm.

Biospecimens (2 samples)
- Sample MMRF_1290_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_1290_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
